Somatic mutation profile of tumor specimen TCGA-VR-AA7B-01A (aliquot TCGA-VR-AA7B-01A-31D-A403-09) from TCGA case TCGA-VR-AA7B, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 65.5 years (23,915 days).
Specimen TCGA-VR-AA7B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e14c77b9-1715-41f9-b9d3-62370075ae4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-AA7B-10A (Blood Derived Normal), aliquot TCGA-VR-AA7B-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2aa0e531-67a9-4aee-8098-4d8ebbd2a1ec

The open-access MAF lists 185 somatic variants for this specimen: 142 protein-altering or splice-affecting, 36 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 36, Nonsense Mutation 13, Frame Shift Del 3, Intron 3, Splice Site 2, RNA 2, Frame Shift Ins 1, In Frame Del 1, Translation Start Site 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TCF4 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs121909121, CM072075; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADAT | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1455646499; called by muse, mutect2, varscan2
- ACE2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as rs146676783; called by muse, mutect2, varscan2
- ANKRD11 | c.3347C>T p.A1116V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as COSV99969075; called by muse, mutect2
- APLP1 | c.1882G>A p.E628K (on ENST00000221891 / NM_001024807.3; = p.E627K on NM_005166.4) | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1385236462; called by muse, mutect2, varscan2
- BEND4 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs552724030; called by muse, mutect2, varscan2
- CCDC60 | c.956G>C p.R319T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV59544284; called by muse, mutect2, varscan2
- CDR1 | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1252346413, COSV65163798; called by muse, mutect2
- CKM | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV55532048; called by muse, mutect2, varscan2
- COG6 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV62995901; called by muse, mutect2, varscan2
- COL19A1 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751938810; called by muse, mutect2, varscan2
- CYLC2 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.424); catalogued as rs1564098086; called by muse, mutect2, varscan2
- ELFN2 | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs894630686; called by muse, mutect2, varscan2
- FAM135B | c.665C>G p.S222* | Nonsense Mutation (SNP) | VAF 7/57 reads (12%) | catalogued as COSV52715151; called by muse, mutect2, varscan2
- FANCB | c.1624C>G p.P542A | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as COSV60759888; called by muse, mutect2
- FASTK | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.382); catalogued as rs756789798, COSV52540552, COSV52541544; called by muse, mutect2, varscan2
- FAT2 | c.4583G>A p.R1528Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756688058, COSV99943537; called by muse, mutect2, varscan2
- FLT3 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54072157; called by muse, mutect2, varscan2
- FMN2 | c.2750G>A p.G917E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.378); catalogued as COSV60419258, COSV60445924; called by muse, mutect2, varscan2
- FOXO1 | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV65427379; called by muse, mutect2
- GNL3L | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs549795452, COSV60576257; called by muse, mutect2, varscan2
- HECW2 | c.4610C>T p.A1537V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs560792476, COSV53671385; called by muse, mutect2, varscan2
- HS3ST6 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs752407140, COSV53536313; called by muse, mutect2, varscan2
- IGSF3 | c.1369C>T p.R457C (on ENST00000369486 / NM_001007237.3; = p.R477C on NM_001542.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs761064394; called by muse, mutect2
- IQSEC3 | c.1106C>T p.A369V (on ENST00000538872 / NM_001170738.2; = p.A66V on NM_015232.1) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs370321433; called by muse, mutect2, varscan2
- KATNAL2 | c.425C>T p.S142L (on ENST00000356157 / NM_001353899.1; = p.S70L on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs750377654, COSV55296536; called by muse, mutect2, varscan2
- KIAA1210 | c.4172G>A p.S1391N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV68178433; called by muse, mutect2, varscan2
- KIF21A | c.4223C>G p.S1408C (on ENST00000361418 / NM_001378440.1; = p.S1395C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV104421337; called by muse, mutect2, varscan2
- KIF21A | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62777983; called by muse, mutect2, varscan2
- LAMA4 | c.2402C>T p.T801M (on ENST00000230538 / NM_001105206.3; = p.T794M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as rs782325644, COSV57901399; ClinVar: uncertain significance; called by muse, mutect2
- LITAF | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs864622744, COSV100243135; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRCC1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV100835332; called by muse, mutect2
- MAGEB6 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100983901; called by muse, mutect2, varscan2
- MCF2L2 | c.2405C>G p.S802* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV61053977; called by muse, mutect2, varscan2
- MIA2 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs139644527; called by muse, mutect2, varscan2
- MUC16 | c.40052C>T p.T13351M | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); catalogued as rs369380417; called by muse, mutect2, varscan2
- NCOA2 | c.3037G>C p.E1013Q | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV51219524; called by muse, mutect2, varscan2
- NLRP7 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.061); catalogued as rs758296123, COSV60177190; called by muse, mutect2, varscan2
- NOL4L | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1568596410; called by muse, mutect2, varscan2
- NR0B2 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs374067965, COSV99574897; called by muse, mutect2, varscan2
- OR13C3 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV101053304; called by muse, mutect2
- OR52N1 | c.638T>C p.I213T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs773631047; called by muse, mutect2, varscan2
- PCDH1 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs1184593221, COSV54611980; called by muse, mutect2, varscan2
- PCDHGA6 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV53997263; called by muse, mutect2, varscan2
- PKHD1L1 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs199719733; called by muse, mutect2, varscan2
- PKHD1L1 | c.7123G>C p.D2375H | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV65743930, COSV65750457; called by muse, mutect2
- PLXND1 | c.5039C>T p.T1680M | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs569800532, COSV60709082; called by muse, mutect2, varscan2
- POGLUT1 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs746467283; called by muse, mutect2, varscan2
- PRKDC | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100038465; called by muse, mutect2, varscan2
- PRSS36 | c.2208C>G p.I736M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as rs1197874229; called by muse, mutect2, varscan2
- PTCH2 | c.2716G>C p.E906Q | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs751579508; called by muse, mutect2, varscan2
- RAPGEF2 | c.3191C>T p.S1064L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs774381651; called by muse, mutect2, varscan2
- RBL2 | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV100043630; called by muse, mutect2, varscan2
- RFPL2 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.502); catalogued as rs770071733, COSV50716765, COSV99964177; called by muse, mutect2, varscan2
- RFX4 | c.889G>A p.A297T (on ENST00000392842 / NM_213594.3; = p.A203T on NM_032491.6) | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57574467; called by muse, mutect2
- SCFD2 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as rs1202060526; called by muse, mutect2, varscan2
- SETD3 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1032276957; called by muse, mutect2, varscan2
- SIPA1L2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.14); catalogued as rs780265795, COSV53395898, COSV99479538; called by muse, mutect2, varscan2
- SYNDIG1L | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0.014); catalogued as rs1225221000; called by muse, mutect2, varscan2
- TAF1 | c.2810C>T p.T937M (on ENST00000373790 / NM_138923.4; = p.T958M on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52124320; called by muse, mutect2, varscan2
- TAS2R30 | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV67855619; called by muse, varscan2
- TCN2 | c.1195C>T p.R399* | Nonsense Mutation (SNP) | VAF 6/51 reads (12%) | catalogued as rs769817524, CM087884; called by muse, mutect2, varscan2
- TMED3 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754708207; called by muse, mutect2, varscan2
- UNC13C | c.3311C>T p.T1104M | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.786); catalogued as rs563857639; called by muse, mutect2, varscan2
- USP6NL | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as rs753637873; called by muse, mutect2, varscan2
- ZNF804B | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60819210, COSV60822900; called by muse, mutect2, varscan2
- ZNRF3 | c.2575C>T p.R859* (on ENST00000544604 / NM_001206998.2; = p.R759* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 31/69 reads (45%) | catalogued as rs1457204359, COSV60433705; called by muse, mutect2, varscan2
- ADGRF5 | c.2942del p.D981Afs*10 | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | called by mutect2, pindel, varscan2
- AKAP5 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ARMCX6 | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ATAD2 | c.1600G>C p.D534H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ATG5 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CBL | c.2658G>C p.E886D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.017); called by muse, mutect2
- CDC26 | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CLCNKA | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CUL1 | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- DBF4 | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- DCAF12L1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- DCAF12L2 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX19A | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- DERA | c.79A>T p.R27W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- DLEC1 | c.4922G>T p.W1641L | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.09); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DMXL2 | c.354G>C p.W118C | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DSP | c.3626_3629dup p.Y1210* | Frame Shift Ins (INS) | VAF 12/19 reads (63%) | called by mutect2, varscan2
- EFTUD2 | c.2313G>C p.Q771H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM114A2 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT2 | c.11125G>A p.E3709K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- FAT2 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- FAT4 | c.10705A>G p.S3569G | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- GPR52 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- HACD3 | c.525G>C p.L175F | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- HIPK2 | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- HYDIN | c.4286C>G p.S1429C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- IQCG | c.925C>G p.H309D | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ITIH2 | c.2406G>C p.Q802H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JAK3 | c.3318G>C p.E1106D | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KMT5B | c.123G>C p.K41N | Missense Mutation (SNP) | VAF 84/160 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, varscan2
- LRRIQ4 | c.43C>G p.H15D | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MACF1 | c.13018C>T p.Q4340* (on ENST00000372915; = p.Q2273* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- MAP3K20 | c.759C>G p.F253L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- MCM3 | c.926_944del p.L309Qfs*25 (on ENST00000229854 / NM_001366374.2; = p.L299Qfs*25 on NM_002388.6 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- METAP2 | c.1093A>G p.T365A | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MLLT10 | c.1921C>T p.H641Y (on ENST00000307729 / NM_001195626.3; = p.H657Y on NM_004641.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- MOSPD2 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MYO15A | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRDE2 | c.2038T>A p.F680I | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10A2 | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- OR52E6 | c.932C>A p.T311K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5B21 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- PAK3 | c.709C>T p.P237S (on ENST00000262836 / NM_001324328.2; = p.P222S on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1L1 | c.12694G>T p.A4232S | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- PLB1 | c.1319_1324+11delinsA p.X440_splice | Splice Site (DEL) | VAF 28/95 reads (29%) | called by pindel, varscan2*
- PLCG1 | c.2043G>T p.M681I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.322); called by muse, varscan2
- POLQ | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- POMT1 | c.-3_9del | Translation Start Site (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- POT1 | c.1309C>G p.H437D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PRB2 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 16/163 reads (10%) | called by muse, mutect2
- PRPF38A | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PRUNE2 | c.4624C>A p.H1542N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, varscan2
- RADX | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.148); called by muse, mutect2
- SENP6 | c.2248_2271del p.I750_F757del | In Frame Del (DEL) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- SGSM1 | c.1769C>A p.T590K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SRCAP | c.7957G>T p.E2653* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2
- ST6GALNAC3 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 31/56 reads (55%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYT4 | c.1214G>A p.W405* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- TAF1D | c.693+1G>C p.X231_splice | Splice Site (SNP) | VAF 6/75 reads (8%) | called by muse, mutect2
- TASOR | c.3569A>G p.Y1190C (on ENST00000355628 / NM_001365636.2; = p.Y814C on NM_015224.3) | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TERF2IP | c.1069G>C p.D357H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM70 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- TXNL4A | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- UBAP2L | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UNC13C | c.2396C>G p.S799C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UNC13C | c.4402C>G p.R1468G | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VPS13D | c.7183C>A p.L2395I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WSCD2 | c.716G>A p.R239K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- ZC3H13 | c.4639_4642del p.E1547Hfs*6 (on ENST00000242848 / NM_001330565.2; = p.E1548Hfs*6 on NM_015070.6) | Frame Shift Del (DEL) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- ZDBF2 | c.5671C>G p.Q1891E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.145); called by mutect2, varscan2
- ZNF292 | c.2530C>A p.Q844K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF79 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF91 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- ZPR1 | c.1146G>C p.E382D | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABHD3 | c.126C>T p.V42= | Silent (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2, varscan2
- AC008397.2 | c.1722C>T p.R574= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs765811198; called by muse, mutect2, varscan2
- ACCS | c.27C>T p.F9= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV55459926; called by muse, mutect2, varscan2
- ACP4 | c.342G>A p.E114= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV54516103; called by mutect2, varscan2
- ANGPT4 | c.1110C>T p.L370= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP36 | c.387G>A p.K129= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99358235; called by muse, mutect2, varscan2
- ASB7 | c.801C>T p.F267= | Silent (SNP) | VAF 27/129 reads (21%) | called by muse, mutect2, varscan2
- ATP2C1 | c.378A>G p.K126= | Silent (SNP) | VAF 64/268 reads (24%) | called by muse, mutect2, varscan2
- EGF | c.2880C>T p.L960= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- FAM135B | c.4080T>G p.T1360= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV52752698, COSV99421935; called by muse, mutect2, varscan2
- FCRL5 | c.1035G>A p.L345= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- FGD4 | c.1440G>A p.E480= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- GLB1L3 | c.576C>T p.S192= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs200592634, COSV66281419; called by muse, mutect2, varscan2
- GLT1D1 | c.720G>A p.K240= (on ENST00000442111 / NM_001366889.1; = p.K160= on NM_144669.3) | Silent (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- GLYAT | c.399C>G p.L133= | Silent (SNP) | VAF 26/52 reads (50%) | called by muse, mutect2, varscan2
- IDH3G | c.852C>T p.C284= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as rs1174952903, COSV99473518; called by muse, mutect2, varscan2
- IGHV5-51 | c.216T>A p.P72= | Silent (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- ITGA2B | c.708G>C p.S236= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV52234219; called by muse, mutect2, varscan2
- KCTD3 | c.2262G>A p.R754= | Silent (SNP) | VAF 21/86 reads (24%) | called by muse, mutect2
- LRRK2 | c.2940G>A p.E980= | Silent (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- MC2R | c.873C>A p.I291= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV59617957; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2382C>T p.V794= | Silent (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- MYH15 | c.2655G>A p.L885= | Silent (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- NLRP12 | c.2298C>T p.L766= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- PCDHGA6 | c.1935C>T p.A645= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as rs761668305; called by muse, mutect2, varscan2
- RBBP6 | c.3195G>A p.E1065= | Silent (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- SH3D21 | c.1455C>T p.V485= (on ENST00000453908 / NM_001162530.2; = p.V374= on NM_024676.5) | Silent (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- SLC9A3R2 | c.555C>T p.A185= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs1292151298; called by muse, mutect2, varscan2
- SLITRK3 | c.1411C>T p.L471= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as rs1476809442; called by muse, mutect2
- THPO | c.765T>C p.S255= (on ENST00000649095 / NM_001290003.1; = p.S115= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- TMEM163 | c.684G>C p.V228= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- UBAP2 | c.1032C>T p.V344= | Silent (SNP) | VAF 18/27 reads (67%) | called by muse, mutect2, varscan2
- UPB1 | c.252C>A p.P84= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV58115463; called by muse, mutect2
- ZDBF2 | c.2766C>A p.I922= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- ZFP91 | c.1407C>T p.L469= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- ZNF180 | c.1644G>A p.P548= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs781643414, COSV55424646; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850909 G>A | 3'Flank (SNP) | VAF 13/29 reads (45%) | catalogued as rs1371356008; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498989 T>A | 5'Flank (SNP) | VAF 11/79 reads (14%) | catalogued as rs754397792; called by muse, mutect2, varscan2
- LRP5L | n.598C>A | RNA (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- NT5E | c.1360+400C>A | Intron (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- SLC7A2 | c.1195+281C>T | Intron (SNP) | VAF 10/27 reads (37%) | catalogued as COSV50262278; called by muse, mutect2, varscan2
- SNORD115-41 | n.65A>C | RNA (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- TP53 | c.993+201G>A | Intron (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
